Somatic mutation profile of tumor specimen 467256db-a312-4346-9ac0-e49e44 (aliquot 467256db-a312-4346-9ac0-e49e44_D6) from CPTAC case 01OV002, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 467256db-a312-4346-9ac0-e49e44: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebf0ef19-f8e0-48fe-8daa-faf36995800c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 2bb86ca8-2768-44d3-8dd8-ebb273 (Blood Derived Normal), aliquot 2bb86ca8-2768-44d3-8dd8-ebb273_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6df79f3f-d42e-4673-b6d1-e93741007245

The open-access MAF lists 63 somatic variants for this specimen: 46 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 12, Nonsense Mutation 6, Splice Site 2, Intron 2, 3'UTR 2, In Frame Del 1, Frame Shift Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs398123102, CM164905, CM940036; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.216dup p.V73Rfs*76 | Frame Shift Ins (INS) | VAF 34/187 reads (18%) | catalogued as rs730882018, COSV104369723; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- AP4E1 | c.2744A>G p.H915R | Missense Mutation (SNP) | VAF 37/322 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs1414072598; called by muse, varscan2
- CACNA1S | c.2994C>A p.D998E | Missense Mutation (SNP) | VAF 97/1154 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs886045798; ClinVar: uncertain significance; called by muse, mutect2
- CCR8 | c.1046C>A p.S349Y | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV58336904; called by muse, mutect2
- CNTNAP1 | c.853C>G p.R285G | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV52853131; called by muse, mutect2, varscan2
- CSMD3 | c.6691C>T p.R2231* (on ENST00000297405 / NM_001363185.1; = p.R2127* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 32/273 reads (12%) | catalogued as rs751474008, COSV52093601, COSV52154452; called by muse, mutect2, varscan2
- CYP2F1 | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV100463094; called by muse, mutect2, varscan2
- GABRR1 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 98/636 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65619795; called by muse, mutect2, varscan2
- PKP4 | c.3313C>G p.Q1105E | Missense Mutation (SNP) | VAF 25/364 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs376621114; called by muse, mutect2
- XYLB | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373645316; called by muse, mutect2, varscan2
- ZNF236 | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 42/507 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1020887633, COSV53489307; called by muse, mutect2
- ASS1 | c.1219A>T p.S407C | Missense Mutation (SNP) | VAF 77/445 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- CCND1 | c.650T>G p.L217R | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CHGA | c.1204A>T p.S402C | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIART | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- DDR2 | c.83-1G>T p.X28_splice | Splice Site (SNP) | VAF 42/356 reads (12%) | called by mutect2, varscan2
- DDX58 | c.1407C>G p.D469E | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2
- DIP2C | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EEF1AKMT2 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMC4 | c.258C>G p.I86M | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- FGD6 | c.2527G>T p.E843* | Nonsense Mutation (SNP) | VAF 33/206 reads (16%) | called by muse, mutect2, varscan2
- GRIN3A | c.1586G>T p.R529M | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- HGFAC | c.839_841+17del p.X280_splice | Splice Site (DEL) | VAF 13/153 reads (8%) | called by mutect2, pindel
- HUWE1 | c.12613G>T p.E4205* | Nonsense Mutation (SNP) | VAF 97/772 reads (13%) | called by muse, mutect2, varscan2
- HUWE1 | c.12612G>T p.K4204N | Missense Mutation (SNP) | VAF 94/684 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- IGHMBP2 | c.1332G>T p.M444I | Missense Mutation (SNP) | VAF 50/342 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KCND1 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 32/309 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2
- KRT8 | c.885_919del p.K295Nfs*3 | Frame Shift Del (DEL) | VAF 55/319 reads (17%) | called by mutect2, pindel, varscan2
- LAMA2 | c.2159C>G p.A720G | Missense Mutation (SNP) | VAF 47/379 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- MYO1G | c.2020C>T p.L674F | Missense Mutation (SNP) | VAF 50/544 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); called by muse, mutect2
- NOTCH1 | c.5090C>A p.T1697N | Missense Mutation (SNP) | VAF 31/592 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.046); called by muse, mutect2
- PABPN1L | c.614T>A p.V205E | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- PCDHGB1 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 83/493 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PCGF6 | c.115G>C p.A39P | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- PNPLA1 | c.429G>T p.E143D (on ENST00000394571 / NM_001374623.1; = p.E48D on NM_173676.2) | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PROM1 | c.236T>A p.F79Y | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SCAP | c.3605G>C p.C1202S | Missense Mutation (SNP) | VAF 59/368 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- SH3BP4 | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 69/381 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- SH3GLB1 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- SHARPIN | c.709T>G p.S237A | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SLC17A5 | c.419G>C p.G140A | Missense Mutation (SNP) | VAF 58/370 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- STXBP3 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 25/231 reads (11%) | called by muse, mutect2, varscan2
- TPST1 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 30/226 reads (13%) | called by muse, mutect2, varscan2
- UNC13C | c.4831A>G p.T1611A | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZDHHC19 | c.861_875del p.L289_A293del | In Frame Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, varscan2
- B9D2 | c.432C>T p.A144= | Silent (SNP) | VAF 98/516 reads (19%) | catalogued as rs778128085, COSV54684905; called by muse, varscan2
- BNIPL | c.774T>C p.H258= | Silent (SNP) | VAF 13/274 reads (5%) | called by muse, mutect2
- CHD5 | c.411C>T p.L137= | Silent (SNP) | VAF 14/250 reads (6%) | catalogued as rs1246663549; called by muse, mutect2
- CSMD1 | c.10380T>C p.F3460= (on ENST00000520002; = p.F3459= on NM_033225.6) | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as rs758007040; called by muse, mutect2, varscan2
- DSC3 | c.288A>C p.I96= | Silent (SNP) | VAF 48/399 reads (12%) | called by muse, mutect2, varscan2
- FAM13C | c.147C>T p.P49= | Silent (SNP) | VAF 16/181 reads (9%) | catalogued as rs375177117; called by muse, mutect2, varscan2
- KLHL6 | c.1038C>T p.S346= | Silent (SNP) | VAF 73/422 reads (17%) | called by muse, mutect2, varscan2
- NT5C1B | c.69A>G p.E23= | Silent (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2
- SERPINB2 | c.216T>G p.T72= | Silent (SNP) | VAF 23/213 reads (11%) | catalogued as rs145713562; called by muse, mutect2, varscan2
- TNFRSF8 | c.750G>A p.L250= | Silent (SNP) | VAF 16/240 reads (7%) | called by muse, mutect2
- TPD52L3 | c.378G>A p.G126= | Silent (SNP) | VAF 29/214 reads (14%) | catalogued as rs746334184; called by muse, mutect2, varscan2
- USP50 | c.543T>A p.T181= (on ENST00000616326; = p.T172= on NM_203494.5) | Silent (SNP) | VAF 42/434 reads (10%) | called by muse, mutect2
- C2CD6 | c.1582-3893G>T | Intron (SNP) | VAF 52/371 reads (14%) | called by muse, mutect2, varscan2
- HOXB6 | c.*24C>T | 3'UTR (SNP) | VAF 82/390 reads (21%) | called by muse, varscan2
- RBM34 | c.365+205T>A | Intron (SNP) | VAF 39/166 reads (23%) | called by muse, mutect2, varscan2
- TAC3 | c.*488G>A | 3'UTR (SNP) | VAF 28/338 reads (8%) | called by muse, mutect2
- TRIP4 | chr15:64387512 C>A | 5'Flank (SNP) | VAF 15/176 reads (9%) | called by muse, mutect2
